Gene-level copy-number profile of tumor specimen TCGA-2G-AAHD-01A from TCGA case TCGA-2G-AAHD, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 39.1 years (14,296 days).
Specimen TCGA-2G-AAHD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 68fce8a4-7f4d-4f7c-ad1e-07b1c1d33ec4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/b896f794-a7d3-4e8e-be4e-22a7e2ee87d3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 117; copy number 2: 7,528; copy number 3: 25,219; copy number 4: 26,030; copy number 5: 23.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 100. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
